CCDI case PBCMBN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4a5f67e3-dbe6-4e28-a27c-45dd218333a0

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (237 days).

Biospecimens (3 samples)
- Sample 0DUXO0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUXOK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUXPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
